Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF4, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAF4-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 3/3/14

Direct dial
Mobile:
Internal postal address
E-mail
Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 6 cm; tumor confined to testis in available slides;
angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Criteria	JW 1/18/14	Yes	No

Source: NCI Genomic Data Commons file 59ce9b0f-d17f-4795-aa13-4f075ee197fc (TCGA-2G-AAF4.955880AE-A0DE-4971-9F81-4A5862152D91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).